Gene-level copy-number profile of tumor specimen TCGA-CR-7399-01A from TCGA case TCGA-CR-7399, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 60.7 years (22,182 days).
Specimen TCGA-CR-7399-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.383597b6-583e-48da-a7e3-9208b1523509.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CR-7399-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ff252fa9-ee83-48c1-b710-d59a1a361893

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,946; copy number 2: 21,342; copy number 3: 23,539; copy number 4: 8,303; copy number 5: 2,482; copy number 6: 1,651; copy number 7: 243; copy number 8: 19; copy number 9: 61; copy number 10: 34; copy number 13: 85; copy number 18: 57; copy number 46: 42; copy number 68: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CR-7399-01A-11D-2010-01): tumor purity 0.51, ploidy 2.94, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 550 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:137,998,735–138,033,655, 1 gene, copy number 7 (within-gene range 5–7): CLDN18.
- chr3:138,061,990–140,577,397, 47 genes, copy number 7 (within-gene range 6–7): DZIP1L, KRT8P36, A4GNT, AC023049.1, DBR1, ARMC8, NME9, MRAS, ESYT3, AC022497.1, CEP70, FAIM, PPIAP72, PIK3CB, GAPDHP39, RPL23AP40, EEF1A1P25, ATP5MC1P3, LINC01391, FOXL2, FOXL2NB, PRR23A, MRPS22, PRR23B, PRR23C, RPL7L1P7, BPESC1, PISRT1, AC119740.1, AC024933.2, AC024933.1, COPB2, U6, AC046134.2, RBP2, AC097103.1, ACTG1P1, RBP1, NMNAT3, AC046134.1, RN7SKP124, RN7SL724P, AC110716.2, AC110716.1, AC016933.1, TRMT112P5, CLSTN2.
- chr3:162,486,541–169,038,416, 57 genes, copy number 7: TOMM22P6, AC128716.1, AC128685.1, LINC01192, RPS6P4, AC079910.1, RNU7-82P, AC084017.1, MIR1263, LINC01323, LINC01324, SI, Y_RNA, LINC02023, SLITRK3, LINC01322, BCHE, MTND4P17, MTND4LP10, MTND3P7, MTCO3P38, MCUR1P2, AC104629.1, LINC01326, AC072046.2, RN7SKP298, PSAT1P4, AC072046.1, CBX1P5, AC069439.2, AC069439.1, PPIAP74, ZBBX, LINC01327, SERPINI2, WDR49, PDCD10, HMGN1P8, SERPINI1, AC079822.1, LRRC77P, AC026353.1, MEMO1P3, AC128713.1, HMGN2P26, GOLIM4, AC069243.1, EGFEM1P, AC124893.1, RNU2-20P, MIR551B, RPSAP33, RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997.
- chr7:87,503,017–92,110,673, 51 genes, copy number 7–9 (within-gene range 6–9): ABCB1, HNRNPA1P9, RUNDC3B, SLC25A40, DBF4, ADAM22, SRI, SRI-AS1, AC003991.1, STEAP4, AC002069.2, EIF4A1P13, AC002069.1, AC002069.4, AC002069.3, KPNA2P2, PQLC1P1, EEF1A1P28, AC002127.1, ZNF804B, TEX47, AC002383.1, RNU6-274P, STEAP2-AS1, AC004969.1, DPY19L2P4, STEAP1, STEAP2, CFAP69, Y_RNA, AC002064.2, AC002064.1, FAM237B, GTPBP10, AC002064.3, CLDN12, AC006153.1, CDK14, AC002456.2, AC002456.1, TVP23CP1, AC002458.1, PTP4A1P3, FZD1, AC079760.2, NIPA2P1, AC079760.1, AC000058.1, MTERF1, AC003086.1, AKAP9.
- chr7:98,877,933–99,050,831, 1 gene, copy number 7 (within-gene range 5–7): TRRAP.
- chr7:98,989,867–100,642,779, 101 genes, copy number 7 (broad region; genes not listed).
- chr7:104,126,341–104,208,047, 1 gene, copy number 7 (within-gene range 5–7): ORC5.
- chr9:4,490,468–7,961,224, 82 genes, copy number 9–68 (broad region; genes not listed).
- chr11:68,980,021–72,843,674, 141 genes, copy number 13–18 (broad region; genes not listed).
- chr11:72,869,544–72,869,650, 1 gene, copy number 13: RNU6-672P.
- chr13:83,145,540–84,069,408, 9 genes, copy number 10: AL512782.1, RNU6-67P, AL353688.1, SLITRK1, AL355481.1, VENTXP2, AL590681.1, UBE2D3P4, AL445604.1.
- chr14:20,110,739–20,436,166, 25 genes, copy number 10: OR4K17, OR4N5, PSMB7P1, GTF2IP22, OR11G1P, OR11P1P, OR11G2, OR11H5P, OR11H6, OR11H7, OR11H4, TTC5, AL356019.2, AL356019.1, CCNB1IP1, AL355075.6, SNORA79B, SNORD126, AL355075.4, RPPH1, PARP2, AL355075.1, TEP1, RNA5SP382, KLHL33.
- chr14:76,495,363–76,726,712, 3 genes, copy number 7 (within-gene range 3–7): AC008050.1, CYCSP1, RPSAP3.
- chr14:77,265,483–77,469,472, 11 genes, copy number 7: NGB, MIR1260A, POMT2, GSTZ1, TMED8, AC007954.1, SAMD15, NOXRED1, VIPAS39, AHSA1, AF111168.1.
- chr17:78,605,233–79,516,148, 19 genes, copy number 8 (within-gene range 3–8): SCAT1, CYTH1, AC099804.1, RNU6-638P, USP36, AC022966.2, RPL9P29, TIMP2, AC022966.1, CEP295NL, AC100788.2, AC100788.1, LGALS3BP, CANT1, C1QTNF1-AS1, C1QTNF1, ENGASE, RBFOX3, AC021534.1.

Autosomal genes at a single copy (total copy number 1): 1,946. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
